Gene-level copy-number profile of tumor specimen TCGA-85-8276-01A from TCGA case TCGA-85-8276, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 62.2 years (22,707 days).
Specimen TCGA-85-8276-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.1fd4b2d0-c968-4e01-851d-ce072e89beee.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-8276-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 810 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/42d52b3a-d7e4-4c77-ac90-65b60add8e9e

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 119; copy number 1: 3,709; copy number 2: 12,237; copy number 3: 14,615; copy number 4: 18,172; copy number 5: 7,591; copy number 6: 676; copy number 7: 1,546; copy number 8: 811; copy number 9: 31; copy number 10: 48; copy number 12: 4; copy number 13: 13; copy number 14: 25; copy number 15: 11; copy number 20: 119; copy number 26: 2; copy number 28: 23; copy number 33: 35; copy number 61: 4; copy number 66: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-8276-01A-11D-2292-01): tumor purity 0.26, ploidy 3.47, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 109 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:137,964,020–138,307,970, 5 genes: HNMT, LINC01832, RPL15P5, YWHAEP5, IDI1P1.
- chr2:213,152,970–213,284,205, 4 genes: AC079610.1, LINC01953, AC079610.2, SPAG16-DT.
- chr3:32,151,083–32,370,321, 6 genes: AC094019.2, RPSAP11, AC097639.1, CMTM8, AC097639.2, KRT18P15.
- chr5:58,969,038–60,522,120, 1 gene (within-gene range 0–2): PDE4D.
- chr5:59,703,606–60,548,813, 9 genes: MIR582, AC034234.1, RNU6-806P, AC109486.1, SETP21, AC109486.2, PART1, AC109486.3, AC016591.1.
- chr5:60,630,514–60,630,973, 1 gene: CAB39P1.
- chr8:3,700,492–3,700,628, 1 gene: RNA5SP251.
- chr8:4,496,392–4,788,584, 3 genes: AC010941.1, AC022068.1, PAICSP4.
- chr9:8,314,246–10,612,723, 1 gene (within-gene range 0–1): PTPRD.
- chr9:8,797,135–13,323,450, 31 genes: RNU7-185P, PTPRD-AS1, AL596451.1, RPS26P3, RN7SL5P, AL513422.1, AL135790.2, PTPRD-AS2, AL135790.1, AL161788.1, IMP3P1, AL162413.1, AKAP8P1, AL451129.1, AL355672.1, AL592227.1, AL353595.1, AL589678.1, JKAMPP1, RNU2-47P, TYRP1, LURAP1L-AS1, RN7SL849P, LURAP1L, Y_RNA, AL161449.2, PRDX1P1, AL161449.1, MPDZ, AL162386.2, AL162386.1.
- chr11:133,532,415–134,067,936, 9 genes: AP004606.1, LINC02743, SPATA19, AP001979.1, IGSF9B, MIR4697, LINC02730, LINC02731, AP000911.1.
- chr14:32,074,946–32,272,301, 8 genes: ARHGAP5-AS1, ARHGAP5, AL161665.1, AL161665.2, RNU6-7, RNU6-8, AL136298.2, KIAA1143P1.
- chr14:32,373,337–32,484,800, 3 genes: AL136298.1, RN7SL660P, MTCO1P2.
- chr14:67,441,855–67,816,590, 22 genes: MIR5694, TMEM229B, PLEKHH1, PIGH, AL132640.1, AL132640.2, AL132640.3, Y_RNA, ARG2, AL049779.4, VTI1B, COX7A2P1, RNA5SP386, AL049779.1, RDH11, RDH12, RN7SL369P, RPL21P9, ZFYVE26, AL049779.3, RN7SL213P, AL049779.2.
- chr14:68,113,706–68,114,144, 1 gene: AL133370.2.
- chr19:34,126,973–34,355,566, 4 genes (within-gene range 0–2): CHCHD2P3, LSM14A, GARRE1, RPL29P33.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 337 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:185,652,374–185,833,290, 4 genes, copy number 12: FSIP2-AS1, U8, FSIP2-AS2, FSIP2.
- chr3:96,617,188–96,619,831, 2 genes, copy number 26: MTRNR2L12, RPL18AP8.
- chr8:37,736,601–39,105,445, 51 genes, copy number 14–66 (within-gene range 7–66): ERLIN2, AC138356.2, PLPBP, ADGRA2, BRF2, RAB11FIP1, AC130304.1, RN7SL709P, GOT1L1, AC144573.1, ADRB3, RPL12P48, EIF4EBP1, AP006545.1, AP006545.3, AP006545.2, ASH2L, RNU6-988P, AC084024.1, STAR, AC084024.3, LSM1, RNU6-323P, BAG4, AC084024.2, AC084024.4, DDHD2, PLPP5, NSD3, AC087362.2, AC087362.1, AC087623.2, LETM2, FGFR1, AC087623.3, AC087623.1, RPS20P22, C8orf86, AC069120.1, RNF5P1, AC016813.1, TACC1, Y_RNA, AC067817.1, AC067817.2, PLEKHA2, AC108863.1, HTRA4, TM2D2, ADAM9, SNORD38D.
- chr8:39,860,219–39,928,790, 3 genes, copy number 15 (within-gene range 3–15): AP005902.2, AP005902.1, IDO1.
- chr8:39,914,229–39,920,890, 2 genes, copy number 15: AC007991.2, AC007991.4.
- chr9:31,165,618–31,645,160, 6 genes, copy number 15: AL354854.1, SLC25A6P2, LINC01243, MTATP6P30, MTCO3P30, HMGB3P23.
- chr11:69,641,156–70,436,584, 27 genes, copy number 10–13: CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 10: AP001271.1.
- chr11:78,652,829–79,441,030, 1 gene, copy number 9 (within-gene range 2–9): TENM4.
- chr11:79,092,848–79,193,160, 2 genes, copy number 9: AP002957.1, AP001547.1.
- chr11:85,336,075–86,069,882, 13 genes, copy number 9 (within-gene range 6–9): AP002803.1, AP003035.1, RNU6-1292P, TMEM126B, TMEM126A, CREBZF, CCDC89, SYTL2, AP000974.1, CCDC83, AP003128.1, SLC25A1P1, PICALM.
- chr11:110,355,130–110,713,189, 3 genes, copy number 9: LINC02732, FDX1, ARHGAP20.
- chr14:21,868,839–23,509,862, 177 genes, copy number 20–33 (broad region; genes not listed).
- chr14:39,147,811–39,170,532, 1 gene, copy number 9 (within-gene range 4–9): TRAPPC6B.
- chr14:39,156,742–40,390,547, 11 genes, copy number 9 (within-gene range 5–9): RPL7AP2, AL132639.3, PNN, AL132639.1, YTHDF2P1, MIA2, AL132639.2, GLRX5P3, COILP1, FBXO33, AL049828.1.
- chr18:14,450,216–15,330,282, 33 genes, copy number 10: LONRF2P1, CXADRP3, GRAMD4P7, POTEC, RNU6-1021P, OR4K7P, OR4K8P, SNX19P3, VN1R74P, GTF2IP8, ANKRD30B, RNU6-1210P, AP006565.1, MIR3156-2, LINC01906, FGF7P1, AP005121.1, LINC01443, LINC01444, AP005121.2, AP005242.4, AP005242.2, AP005242.3, AP005242.1, AP005242.5, AP005901.2, AP005901.6, AP005901.5, AP005901.3, BNIP3P3, AP005901.4, AP005901.1, RNU6-721P.

Autosomal genes at a single copy (total copy number 1): 1,298. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
